CCDI case PBBTYW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b5f8b2d5-abce-4901-ae2c-5565ee9d61ea

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, spindle cell: ICD-O-3 morphology code: 9041/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 15.2 years (5,547 days).

Biospecimens (3 samples)
- Sample 0DH5UA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH5VG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH5XM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
